Gene-level copy-number profile of tumor specimen TCGA-DX-A23V-01A from TCGA case TCGA-DX-A23V, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 57.9 years (21,155 days).
Specimen TCGA-DX-A23V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.bc5eb179-acb9-424a-a37f-19a9a3e52f96.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A23V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0e2b00d-9e8b-43a2-a983-0f246cefa05c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 59,383; copy number 3: 41; copy number 4: 39; copy number 5: 48; copy number 6: 107; copy number 7: 50; copy number 8: 52; copy number 9: 45; copy number 10: 51; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A23V-01A-11D-A29M-01): tumor purity 0.44, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 354 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,173,433–56,524,495, 1 gene, copy number 6 (within-gene range 2–6): AC119674.2.
- chr1:56,414,935–56,645,301, 3 genes, copy number 6 (within-gene range 2–6): LINC01767, PLPP3, RPL21P23.
- chr1:58,047,889–60,149,784, 33 genes, copy number 5–10: HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778.
- chr1:78,889,764–79,522,203, 6 genes, copy number 10: ADGRL4, PSAT1P3, AL353651.2, AL353651.1, LINC02792, ADH5P2.
- chr1:80,283,352–80,646,791, 7 genes, copy number 6–10 (within-gene range 2–10): HMGB1P18, AL606519.1, HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781.
- chr1:81,208,568–81,992,436, 12 genes, copy number 5: AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20.
- chr1:83,979,118–84,238,498, 6 genes, copy number 10 (within-gene range 2–10): TTLL7-IT1, AC104454.1, AC104454.2, AL359504.1, PRKACB, TXN2P1.
- chr1:85,249,953–85,448,124, 4 genes, copy number 5 (within-gene range 2–5): C1orf52, Y_RNA, BCL10, AL078459.1.
- chr1:89,181,144–89,426,243, 10 genes, copy number 6: GBP4, AC099063.4, AC099063.3, GBP5, AC099063.1, AC099063.2, BX119321.1, GBP6, CAPNS1P1, GBP1P1.
- chr1:94,145,111–94,145,619, 1 gene, copy number 11: AC093579.1.
- chr12:57,546,026–58,244,865, 40 genes, copy number 8 (within-gene range 2–8): KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:64,759,496–64,977,509, 1 gene, copy number 7 (within-gene range 2–7): AC078815.1.
- chr12:64,867,956–65,121,305, 7 genes, copy number 7 (within-gene range 3–7): RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P.
- chr12:65,758,020–65,966,291, 5 genes, copy number 6: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:67,329,014–67,352,039, 2 genes, copy number 6: AC078983.1, MRPL40P1.
- chr12:67,443,105–67,970,017, 7 genes, copy number 10 (within-gene range 2–10): LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479.
- chr12:68,272,443–70,243,379, 50 genes, copy number 5–9 (within-gene range 2–9): MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1.
- chr12:74,170,445–74,171,830, 1 gene, copy number 8: AC090502.3.
- chr12:94,897,055–95,442,482, 14 genes, copy number 6: NDUFA12, NR2C1, FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P.
- chr12:96,278,261–96,875,555, 6 genes, copy number 9: CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54.
- chr12:98,931,682–98,976,656, 1 gene, copy number 8: AC069437.1.
- chr12:100,026,248–100,628,288, 17 genes, copy number 5–10: AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2, SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1.
- chr12:101,745,499–102,012,130, 13 genes, copy number 7 (within-gene range 2–7): GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2.
- chr12:102,120,183–102,197,833, 2 genes, copy number 9 (within-gene range 2–9): PARPBP, PMCH.
- chr12:102,217,318–102,230,533, 2 genes, copy number 9: RN7SL793P, AC093023.1.
- chr12:103,587,273–103,766,719, 1 gene, copy number 8 (within-gene range 3–8): STAB2.
- chr12:103,654,780–103,953,645, 9 genes, copy number 8 (within-gene range 2–8): AC025265.2, AC025265.3, AC025265.1, NT5DC3, AC012555.2, AC012555.1, TTC41P, HSP90B1, MIR3652.
- chr12:108,281,103–108,339,317, 2 genes, copy number 7: AC009729.1, CMKLR1.
- chr12:110,049,360–110,073,686, 1 gene, copy number 6 (within-gene range 2–6): AC007546.3.
- chr12:110,124,335–112,382,439, 65 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:113,098,819–113,391,629, 14 genes, copy number 7 (within-gene range 2–7): RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2.
- chr12:113,583,886–113,966,325, 5 genes, copy number 5 (within-gene range 2–5): LINC01234, DYNLL1P4, RBM19, AC009731.1, AC073863.1.
- chr12:116,357,578–116,389,471, 2 genes, copy number 6 (within-gene range 4–6): AC079384.2, AC079384.1.
- chr13:103,343,660–104,134,257, 4 genes, copy number 6: AL162717.1, LINC01309, ATP6V1G1P7, AL136524.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
